Gene-level copy-number profile of tumor specimen TCGA-C5-A901-01A from TCGA case TCGA-C5-A901, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G2; Age at diagnosis: 44.3 years (16,186 days).
Specimen TCGA-C5-A901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.18669945-c816-4819-97be-491d1763f144.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A901-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/730d771e-ccff-49ba-947e-f20034a49348

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,413; copy number 2: 46,663; copy number 3: 4,864; copy number 4: 2,638; copy number 5: 277; copy number 6: 530; copy number 7: 76; copy number 9: 134; copy number 10: 222.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:72,080,331–72,110,782, 3 genes (within-gene range 0–3): AP000812.4, LRTOMT, LAMTOR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,239 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,754,216–62,710,694, 604 genes, copy number 6–10 (broad region; genes not listed).
- chr3:186,454,969–198,222,513, 277 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:27,523,431–27,972,733, 20 genes, copy number 6: PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2.
- chr12:28,163,298–28,190,738, 3 genes, copy number 6: AC022364.1, AC022364.2, AC022079.2.
- chr19:36,259,540–39,182,816, 125 genes, copy number 10 (within-gene range 1–10) (broad region; genes not listed).
- chr19:39,679,374–41,137,308, 76 genes, copy number 7 (broad region; genes not listed).
- chr19:41,998,321–44,765,464, 134 genes, copy number 9 (within-gene range 1–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
